CCG case CUPP-B5XB — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/60ccb926-8283-4d59-ac27-5d28c7eb3c2e

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Japan; Year of birth: 1940; Vital status: Dead; Days to death: 648 days (1.8 years); Year of death: 2011; Cause of death: Cancer Related.

Diagnoses (3)
1. Carcinoma, metastatic, NOS (the primary disease): ICD-O-3 morphology code: 8010/6; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Lymph node, NOS; Classification of tumor: metastasis; Age at diagnosis: 69.5 years (25,388 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; AJCC staging edition: 8th; AJCC clinical T: TX; AJCC clinical N: N4; AJCC clinical M: M0; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N4; AJCC pathologic M: M0; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Sites of involvement: Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 1; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: R2; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Radiation Therapy, NOS, postoperative.
2. Carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8010/6; Tissue or organ of origin: Liver; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Radiation Therapy, NOS; Surgery, NOS.
3. Progression of the lymph node (histology not recorded by GDC). Age at diagnosis: 70.1 years (25,610 days); Year of diagnosis: 2010; Days to diagnosis: 222 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Complete Response.

Follow-up (3 entries)
- Day 222 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 222 days.
- Days to follow up: 306 days; Disease response: With Tumor.
- Follow-up contact recording only the day: day 648.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 166 cm; BMI: 22.5.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Tobacco smoking onset year: 1970; Tobacco smoking quit year: 2008.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B5XB-TTM1-A: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B5XB-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 70; Percent normal cells: 25; Percent necrosis: 30; Percent stromal cells: 5; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 2.
